Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANU, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANU-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type: **Redacted**
*Date - Date of Service: **Redacted**
Document Status: **Redacted**
Document Title: **Redacted**
Author: **Redacted**
Authenticated By: **Redacted**
Encounter info: **Redacted**
Contributor system: **Redacted**

* Final Report *

MICROSCOPIC EXAMINATION:

See final microscopic-diagnosis.

GROSS EXAMINATION:

The specimen is received fresh from the O.R. and labeled "Right testicle & cord". It consists of a 103-gram radical orchiectomy specimen consisting of testicle (6.5 x 4.7 x 4.5 cm), epididymis (4.0 x 1.0 x 0.8 cm), spermatic cord (10 x 2 x 1.2 cm).

Bivalving the specimen reveals a 5.1 x 4.2 x 4.2 cm tumor replacing the lower portion of the testicle. The cut surface shows focal cystic, cartilaginous, and hemorrhagic areas. The tumor is variegated tan-gray to yellow. The tumor does not appear to grossly involve the epididymis. The tunica albuginea is smooth, without involvement by tumor. The uninvolved superior portion of testis is brown and stringy. Representative sections are submitted in 14 cassettes.

SECTIONS:

A1: spermatic cord resection margin
A2: mid spermatic cord
A3: paratesticular spermatic cord
A4-12: tumor
A13: epididymis
A14: uninvolved parenchyma

ICD-O-3

Mixed germ cell tumor
9085/3

Site R Testis NOS
C62.9

Signature Line

W 3/31/14

CLINICAL INFORMATION:

Pre-Op Dx: Right testicular mass cancer
Post-Op Dx: Right testicular mass cancer

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

* Final Report *

SPECIMEN SOURCE:

"Right testicle & cord"

DIAGNOSIS:

RIGHT RADICAL ORCHIECTOMY:

- MIXED GERM CELL TUMOR (5.1 x 4.2 x 4.2 CM) CONSISTING OF TERATOMA (45%), EMBRYONAL CARCINOMA (45%), CHORIOCARCINOMA AND YOLK SAC TUMOR (5% EACH)
- TUMOR LIMITED TO THE TESTIS WITHOUT INVOLVEMENT OF EPIDIDYMIS OR TUNICA VAGINALIS
- ADJACENT INTRATUBULAR GERM CELL NEOPLASIA IDENTIFIED
- NO LYMPHOVASCULAR INVASION IDENTIFIED
- ALL MARGINS ARE FREE OF TUMOR

PATHOLOGIC TNM STAGING: pT1NXMX

Signature Line

Electronically signed by

Verified:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

*Pw TSS dx discrepancy from
TCGA tumor is Embryonal 50%
Yolk sac 50%*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Teratoma 45% Embryonal 45% Choriocarcinoma 5% Yolk Sac Tumor 5%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Embryonal Carcinoma 50% Yolk Sac Tumor 50%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 9cfe9d8f-896b-457c-a376-be14904d6683 (TCGA-XE-AANU-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).